Somatic mutation profile of tumor specimen TCGA-77-8153-01A (aliquot TCGA-77-8153-01A-11D-2395-08) from TCGA case TCGA-77-8153, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.4 years (28,253 days).
Specimen TCGA-77-8153-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) defdb51c-39e7-490a-9dce-afdd842523b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8153-11A (Solid Tissue Normal), aliquot TCGA-77-8153-11A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bab91c3-6f06-4cbd-9787-515bf081c15f

The open-access MAF lists 180 somatic variants for this specimen: 133 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 44, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 2, Splice Region 2, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 27/159 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: drug response / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2389T>A p.L797I | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99686116; called by muse, mutect2, varscan2
- ACCSL | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101122222; called by muse, varscan2
- AKAP4 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as COSV100654302; called by muse, mutect2
- ALDH7A1 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV100778275; called by muse, mutect2, varscan2
- ALG13 | c.2978A>G p.Y993C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs764187466, COSV99322497; called by muse, mutect2, varscan2
- AQR | c.3801G>C p.Q1267H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99334191; called by muse, mutect2, varscan2
- ATF4 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100307738; called by muse, mutect2, varscan2
- BMP4 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99817011; called by muse, mutect2
- BRI3BP | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.402); catalogued as rs1352486932, COSV100413070; called by muse, mutect2, varscan2
- C6 | c.301T>G p.S101A | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV99667341; called by muse, mutect2, varscan2
- CABIN1 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99573496; called by muse, mutect2, varscan2
- CARD8 | c.721C>T p.P241S (on ENST00000651546 / NM_001184900.3; = p.P191S on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100751139; called by muse, mutect2, varscan2
- CCDC136 | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs746867895, COSV99922765; called by muse, mutect2, varscan2
- CCDC58 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV99360522; called by muse, mutect2, varscan2
- CCNA1 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 105/156 reads (67%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV55223113, COSV99714673; called by muse, mutect2, varscan2
- CDKL3 | c.594T>A p.N198K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV99527936; called by muse, mutect2, varscan2
- CHRFAM7A | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100241633; called by muse, mutect2, varscan2
- CLDN10 | c.357G>T p.L119F | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT tolerated (0.9); PolyPhen benign (0.02); catalogued as COSV100176184; called by muse, mutect2, varscan2
- COBL | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV54361158; called by muse, mutect2, varscan2
- COL12A1 | c.1451A>G p.Y484C | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100486178; called by muse, mutect2, varscan2
- COL15A1 | c.3986C>A p.P1329H | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100897828; called by muse, mutect2, varscan2
- CST4 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1160956711, COSV99463275; called by muse, mutect2, varscan2
- DCX | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100576547; called by muse, mutect2, varscan2
- DHFR2 | c.143A>C p.Q48P | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100113333; called by muse, mutect2, varscan2
- DMD | c.8920C>G p.H2974D | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100627979; called by muse, mutect2, varscan2
- DMD | c.587T>A p.L196Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99923555; called by muse, mutect2, varscan2
- DPYSL3 | c.40-2A>G p.X14_splice | Splice Site (SNP) | VAF 31/55 reads (56%) | catalogued as COSV100575208; called by muse, mutect2, varscan2
- DUSP21 | c.236C>A p.S79* | Nonsense Mutation (SNP) | VAF 70/247 reads (28%) | catalogued as COSV100173619, COSV59133623; called by muse, mutect2, varscan2
- E2F2 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100674826; called by muse, mutect2, varscan2
- E2F2 | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100674827; called by muse, mutect2, varscan2
- ERP44 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV99316514; called by muse, mutect2, varscan2
- ESPL1 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV99229459; called by muse, mutect2, varscan2
- FAIM2 | c.799T>A p.L267M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as COSV100277598; called by muse, mutect2
- FGD6 | c.2213A>C p.K738T | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV100676670; called by muse, mutect2, varscan2
- GCN1 | c.7410G>T p.L2470F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV100325496; called by muse, mutect2, varscan2
- GPR139 | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV100429919; called by muse, mutect2
- HERC2 | c.2947A>T p.R983* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99874794; called by muse, mutect2, varscan2
- IFNA5 | c.7T>A p.L3M | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV99423706; called by muse, mutect2, varscan2
- IL27RA | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV99652232; called by muse, mutect2, varscan2
- ITFG2 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99958200; called by muse, mutect2, varscan2
- KEAP1 | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99407954; called by muse, mutect2, varscan2
- KIF19 | c.2318A>G p.E773G | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100739104; called by muse, mutect2
- KMT2D | c.6287A>T p.K2096M | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV99983263; called by muse, mutect2, varscan2
- LCT | c.3496G>T p.D1166Y | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99929769; called by muse, mutect2, varscan2
- LENG8 | c.488C>G p.S163W | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV100457676, COSV58727314; called by muse, mutect2, varscan2
- LMBRD1 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs748794025, COSV100992633; called by muse, mutect2, varscan2
- LOXL1 | c.1310A>T p.N437I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV99985352; called by muse, mutect2, varscan2
- LPP | c.731A>T p.Y244F | Missense Mutation (SNP) | VAF 116/195 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100447701; called by muse, mutect2, varscan2
- LRBA | c.7268G>T p.W2423L | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100841797; called by muse, mutect2, varscan2
- LRP1B | c.4472C>T p.T1491I | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101257935; called by muse, mutect2, varscan2
- LRRK2 | c.2938G>C p.E980Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV100110594; called by muse, mutect2, varscan2
- LSG1 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 216/388 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as COSV99503329; called by muse, mutect2, varscan2
- MAP1A | c.4949G>T p.W1650L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100288840; called by muse, mutect2, varscan2
- MDC1 | c.5651C>G p.T1884S | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV100902902; called by muse, mutect2
- MED27 | c.804C>A p.T268= | Splice Region (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99406700; called by muse, mutect2, varscan2
- MOGAT1 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.837); catalogued as COSV101490100; called by muse, mutect2, varscan2
- MSH4 | c.2712G>T p.L904F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.594); catalogued as COSV99591902; called by muse, mutect2, varscan2
- MYH8 | c.1349T>A p.L450Q | Missense Mutation (SNP) | VAF 145/386 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101238477; called by muse, mutect2, varscan2
- MYO18A | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1401765915, COSV62862502; called by muse, mutect2, varscan2
- NAGLU | c.2108A>G p.Q703R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1420441084, COSV99864219; called by muse, mutect2, varscan2
- NARS2 | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99807305; called by muse, mutect2, varscan2
- NHS | c.1340G>T p.R447M | Missense Mutation (SNP) | VAF 201/419 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101196724; called by muse, mutect2, varscan2
- NHS | c.1341G>T p.R447S | Missense Mutation (SNP) | VAF 195/410 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101196725; called by muse, mutect2, varscan2
- NKAIN1 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99744571; called by muse, mutect2, varscan2
- NOS1 | c.4138G>C p.E1380Q | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.763); catalogued as COSV100500838; called by muse, mutect2, varscan2
- NRDC | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.415); catalogued as rs778861367, COSV100703518; called by muse, mutect2, varscan2
- OR1E2 | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV99943453; called by muse, mutect2, varscan2
- OR2S2 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV100558612; called by muse, mutect2, varscan2
- OR2T12 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs764836025, COSV58776972; called by muse, mutect2, varscan2
- OR2T35 | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV100442322; called by muse, mutect2, varscan2
- OR4C12 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs571026380, COSV58859721, COSV58861246; called by muse, mutect2, varscan2
- OR5R1 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100393491; called by muse, mutect2
- OR6Y1 | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100225572, COSV56931120; called by muse, mutect2, varscan2
- OTOF | c.4242G>T p.E1414D (on ENST00000272371 / NM_194248.3; = p.E647D on NM_004802.4) | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV99718090; called by muse, mutect2, varscan2
- PAQR3 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99785188; called by muse, mutect2, varscan2
- PEAK1 | c.4665C>A p.N1555K | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433163; called by muse, mutect2, varscan2
- PGAP1 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100698245; called by muse, mutect2, varscan2
- PNKP | c.150A>G p.Q50= | Splice Region (SNP) | VAF 63/111 reads (57%) | catalogued as COSV100465418; called by muse, mutect2, varscan2
- PRDM4 | c.518A>G p.H173R | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as rs750319192, COSV99946648; called by muse, mutect2, varscan2
- PRKAR2B | c.632G>A p.C211Y | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99708375; called by muse, mutect2, varscan2
- PRKCA | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs761072166, COSV99435146; called by muse, mutect2, varscan2
- QDPR | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 50/77 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV99845866; called by muse, mutect2, varscan2
- RAB33B | c.434T>A p.L145H | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99978217; called by muse, mutect2
- RB1 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 44/58 reads (76%) | catalogued as COSV57295365, COSV99925356; called by muse, mutect2, varscan2
- RBMXL2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.799); catalogued as rs753958920, COSV100182315; called by muse, mutect2, varscan2
- RFX6 | c.457T>C p.C153R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263883; called by muse, mutect2, varscan2
- RYR2 | c.7684A>T p.T2562S | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100771283; called by muse, mutect2, varscan2
- SBNO1 | c.2394T>A p.D798E (on ENST00000420886; = p.D797E on NM_018183.5) | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); catalogued as COSV99929341; called by muse, mutect2, varscan2
- SEC63 | c.775C>G p.Q259E | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV100938421; called by muse, mutect2, varscan2
- SELPLG | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368817681; called by muse, mutect2, varscan2
- SH2D3C | c.1917-1G>T p.X639_splice (on ENST00000314830 / NM_170600.3; = p.X482_splice on NM_005489.4) | Splice Site (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100137107; called by muse, mutect2, varscan2
- SKIL | c.550A>C p.N184H | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99378319; called by muse, mutect2, varscan2
- SLC22A13 | c.1448T>C p.L483P | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs1458081768, COSV100314595; called by muse, mutect2, varscan2
- SLC22A2 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs368700617; called by muse, mutect2, varscan2
- SLC30A2 | c.78A>T p.E26D | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100958570; called by muse, mutect2, varscan2
- SLC35G2 | c.215T>C p.M72T | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV101262049; called by muse, mutect2, varscan2
- SLC6A3 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 42/500 reads (8%) | catalogued as COSV54364575; called by muse, mutect2
- SLITRK3 | c.2870G>A p.R957K | Missense Mutation (SNP) | VAF 224/422 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.424); catalogued as COSV99072037, COSV99579500; called by muse, mutect2, varscan2
- SNX7 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.396); catalogued as COSV100069194, COSV100069300; called by muse, mutect2, varscan2
- SPARCL1 | c.1636G>C p.A546P | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.041); catalogued as COSV99215693; called by muse, mutect2, varscan2
- SPTA1 | c.1763A>T p.Y588F | Missense Mutation (SNP) | VAF 128/352 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.039); catalogued as COSV100935139, COSV63752227; called by muse, mutect2, varscan2
- SYNE1 | c.12064A>T p.S4022C (on ENST00000367255 / NM_182961.4; = p.S3951C on NM_033071.3) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99569137; called by muse, mutect2, varscan2
- SYNE1 | c.7360G>T p.D2454Y (on ENST00000367255 / NM_182961.4; = p.D2461Y on NM_033071.3) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99569141; called by muse, mutect2, varscan2
- TCTEX1D1 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99259229; called by muse, mutect2, varscan2
- TENM4 | c.2634C>G p.I878M | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV99575924, COSV99577207; called by muse, mutect2, varscan2
- TG | c.2405T>C p.L802P | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1391910312, COSV99601636; called by muse, mutect2, varscan2
- TMC5 | c.265A>C p.N89H | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1332755304, COSV101196766; called by muse, mutect2, varscan2
- TOR4A | c.887A>G p.Y296C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1207348462, COSV100677749; called by muse, mutect2, varscan2
- TRAV12-1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.789); catalogued as rs951012895; called by muse, mutect2, varscan2
- TTN | c.50731C>T p.R16911C (on ENST00000591111; = p.R9487C on NM_003319.4) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | PolyPhen probably damaging (0.998); catalogued as rs763966394, COSV59991006; called by muse, mutect2, varscan2
- TTN | c.12610G>A p.E4204K (on ENST00000591111; = p.E4158K on NM_003319.4) | Missense Mutation (SNP) | VAF 69/233 reads (30%) | catalogued as COSV100618609; called by muse, mutect2, varscan2
- UGT2B28 | c.796T>A p.F266I | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100158869; called by muse, mutect2
- UTP15 | c.274G>C p.G92R | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57140829, COSV99706978, COSV99707055; called by muse, mutect2, varscan2
- VAV3 | c.884T>A p.I295N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100579942; called by muse, mutect2, varscan2
- VCAM1 | c.1638G>C p.W546C | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99658673; called by muse, mutect2, varscan2
- VWF | c.7523G>T p.G2508V | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54634402, COSV99779431; called by muse, mutect2, varscan2
- VXN | c.572A>T p.K191M | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100560047; called by muse, mutect2, varscan2
- WASHC2C | c.2474G>A p.G825E | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as COSV100314074; called by muse, mutect2, varscan2
- YY1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1311918952, COSV99216875; called by muse, mutect2
- ZNF225 | c.503A>C p.Q168P | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV99489514; called by muse, mutect2, varscan2
- ZNF250 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 41/86 reads (48%) | catalogued as COSV99480907; called by muse, mutect2, varscan2
- ZNF274 | c.1487C>T p.T496M (on ENST00000610905; = p.T391M on NM_016324.3) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs772196015, COSV100465225; called by muse, mutect2, varscan2
- ZNF436 | c.1302C>G p.I434M | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.178); catalogued as COSV100011161, COSV100011263; called by muse, mutect2, varscan2
- ZNF483 | c.1895A>G p.E632G | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100492985; called by muse, mutect2, varscan2
- ZNF653 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV99542194; called by muse, varscan2
- ZNF705A | c.301T>A p.S101T | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV100828330; called by muse, mutect2, varscan2
- ZSCAN20 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792667; called by muse, mutect2, varscan2
- FGF16 | c.564del p.R189Gfs*3 | Frame Shift Del (DEL) | VAF 119/265 reads (45%) | called by mutect2, pindel, varscan2
- KIF3B | c.792del p.A265Lfs*18 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- RARB | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 69/115 reads (60%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- SLC22A14 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 100/155 reads (65%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2
- TAF13 | c.144_151del p.P49* | Frame Shift Del (DEL) | VAF 37/146 reads (25%) | called by mutect2, pindel, varscan2
- ABCA3 | c.2409G>A p.T803= | Silent (SNP) | VAF 115/206 reads (56%) | catalogued as rs777406810, COSV100068737; called by muse, mutect2, varscan2
- ACOX3 | c.177T>C p.P59= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as COSV100711980; called by muse, mutect2, varscan2
- ACSBG1 | c.780T>C p.P260= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as rs1342565664, COSV99357570; called by muse, mutect2, varscan2
- ACTA1 | c.1005G>A p.P335= | Silent (SNP) | VAF 71/185 reads (38%) | catalogued as rs763219295, COSV100796760; called by muse, mutect2, varscan2
- ADAM19 | c.885T>C p.H295= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99977612; called by muse, mutect2, varscan2
- ANK2 | c.4146C>T p.Y1382= | Silent (SNP) | VAF 59/95 reads (62%) | catalogued as rs761142483, COSV100001911; ClinVar: likely benign; called by muse, mutect2, varscan2
- BIRC5 | c.57C>T p.I19= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100051381; called by muse, mutect2, varscan2
- BYSL | c.150G>T p.V50= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99539879; called by muse, mutect2, varscan2
- CDAN1 | c.1785C>T p.I595= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV100661349; called by muse, mutect2
- CNTRL | c.2475G>T p.G825= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV53047472, COSV99442828; called by muse, mutect2, varscan2
- CP | c.2100T>C p.L700= | Silent (SNP) | VAF 60/285 reads (21%) | catalogued as COSV99224232; called by muse, mutect2, varscan2
- ELP2 | c.1947T>C p.P649= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV100626906; called by muse, mutect2, varscan2
- FAM187B | c.474C>A p.G158= | Silent (SNP) | VAF 52/198 reads (26%) | catalogued as COSV100220021, COSV61201239; called by muse, mutect2, varscan2
- FAT4 | c.12462A>T p.A4154= | Silent (SNP) | VAF 64/102 reads (63%) | catalogued as COSV100629063, COSV58693180; called by muse, mutect2, varscan2
- GDF1 | c.238C>A p.R80= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99439831; called by muse, mutect2, varscan2
- GPR137C | c.888T>C p.S296= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs772320597, COSV100397683, COSV58705169; called by muse, mutect2, varscan2
- H2AC6 | c.99C>T p.R33= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100019958; called by muse, mutect2, varscan2
- IAH1 | c.333A>G p.L111= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs373001388; called by muse, mutect2, varscan2
- INPPL1 | c.3333G>A p.G1111= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99996346; called by muse, mutect2, varscan2
- KIF21B | c.4698G>A p.A1566= (on ENST00000422435 / NM_001252100.2; = p.A1553= on NM_017596.4) | Silent (SNP) | VAF 75/240 reads (31%) | catalogued as rs751378190, COSV59757842; called by muse, mutect2, varscan2
- NCAN | c.3375C>T p.S1125= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs757463600, COSV99387587; called by muse, mutect2, varscan2
- OR4S1 | c.21G>T p.V7= | Silent (SNP) | VAF 140/438 reads (32%) | catalogued as COSV60679477, COSV60679840; called by muse, mutect2, varscan2
- OR6C65 | c.384A>G p.L128= | Silent (SNP) | VAF 102/218 reads (47%) | catalogued as rs774593946, COSV101110193; called by muse, mutect2, varscan2
- PDAP1 | c.390C>T p.A130= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as rs757857148, COSV99402971; called by muse, mutect2, varscan2
- PDCD11 | c.240G>T p.L80= | Silent (SNP) | VAF 81/133 reads (61%) | catalogued as COSV100874372; called by muse, mutect2, varscan2
- PNPLA6 | c.357C>G p.T119= (on ENST00000414982 / NM_001166111.2; = p.T71= on NM_006702.5) | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV99653943; called by muse, mutect2, varscan2
- RAI1 | c.5535G>A p.L1845= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1206595606, COSV99884347; called by muse, mutect2, varscan2
- RBM33 | c.3249A>T p.P1083= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100355307; called by muse, mutect2, varscan2
- RUNX1T1 | c.1368G>T p.V456= (on ENST00000265814 / NM_001198628.1; = p.V429= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99752878; called by muse, mutect2, varscan2
- SENP8 | c.255T>C p.V85= | Silent (SNP) | VAF 48/161 reads (30%) | catalogued as COSV100566554; called by muse, mutect2, varscan2
- SESTD1 | c.1191A>G p.L397= | Silent (SNP) | VAF 69/129 reads (53%) | catalogued as COSV100090640; called by muse, mutect2, varscan2
- SF3B3 | c.387C>G p.A129= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100210007; called by muse, mutect2
- SIRT5 | c.498T>C p.C166= | Silent (SNP) | VAF 15/156 reads (10%) | catalogued as rs746112544; called by muse, mutect2
- SLC14A1 | c.909G>A p.A303= | Silent (SNP) | VAF 54/154 reads (35%) | catalogued as rs765752507, COSV58935336; called by muse, mutect2, varscan2
- SLC16A6 | c.936C>T p.S312= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs782237944, COSV100517339; called by muse, mutect2, varscan2
- TBC1D22B | c.1416A>G p.L472= | Silent (SNP) | VAF 92/232 reads (40%) | catalogued as COSV100996841; called by muse, mutect2, varscan2
- THSD7A | c.1926G>C p.T642= | Silent (SNP) | VAF 72/91 reads (79%) | catalogued as rs542231968, COSV101448782, COSV70262369; called by muse, mutect2, varscan2
- TMEM132D | c.1896G>T p.G632= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV101242931; called by muse, mutect2
- TNN | c.2070C>A p.A690= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as COSV99512243; called by muse, mutect2, varscan2
- UGDH | c.1416A>T p.P472= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV100328520; called by muse, mutect2
- XIRP2 | c.4323G>A p.R1441= (on ENST00000628543; = p.R1616= on NM_152381.6) | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV54702766, COSV99744317; called by muse, mutect2, varscan2
- ZNF217 | c.1827C>T p.D609= | Silent (SNP) | VAF 63/106 reads (59%) | catalogued as rs764565530, COSV100184558; called by muse, mutect2, varscan2
- ZNF461 | c.1530A>T p.S510= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV100831438; called by muse, mutect2, varscan2
- ZSCAN20 | c.309G>A p.L103= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100792664; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840369 A>C | 5'Flank (SNP) | VAF 10/127 reads (8%) | catalogued as COSV100006904; called by muse, mutect2
- MSL3 | c.1171+41C>G | Intron (SNP) | VAF 84/205 reads (41%) | catalogued as COSV100384917; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3184G>T | Intron (SNP) | VAF 49/147 reads (33%) | catalogued as COSV100314454; called by muse, mutect2, varscan2
